TCGA case TCGA-29-1701 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/86b513ba-df09-485d-92d4-fb9e888f7350

Demographics
Sex at birth: female; Race: white; Age at index: 56 years; Vital status: Dead; Days to death: 515 days (1.4 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 56.8 years (20,737 days); Year of diagnosis: 2004; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No.
   Pathology details: Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 31 days; Days to treatment end: 160 days; Number of cycles: 5; Treatment dose: 4,505 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 31 days; Days to treatment end: 160 days; Number of cycles: 5; Treatment dose: 1,280 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 318 days; Days to treatment end: 381 days (1.0 years); Number of cycles: 3; Treatment dose: 75 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease; Days to treatment start: 409 days (1.1 years); Days to treatment end: 472 days (1.3 years); Number of cycles: 3; Treatment dose: 6 AUC; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 57.6 years (21,035 days); Days to diagnosis: 298 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (4 entries)
- Day 298 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 298 days; Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 514 days (1.4 years); Disease response: With Tumor.
- Days to follow up: 515 days (1.4 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Post Adjuvant Therapy.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-29-1701-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.3; Intermediate dimension: 1.1; Shortest dimension: 0.6.
  Slide TCGA-29-1701-01A-01-TS1: Section location: Top; Percent tumor cells: 98; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0.
  Slide TCGA-29-1701-01A-01-BS1: Section location: Bottom; Percent tumor cells: 98; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0.
- Sample TCGA-29-1701-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Doxil.
- Drug treatment 4: Therapy regimen: Progression.
- Follow-up form: Treatment outcome first course: Partial Remission/Response; Tumor status: With tumor; Performance status timing: Post-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 515 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 515 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 298 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-29-1701-01A-01D-0559-01): tumor purity 0.71, ploidy 3.35, whole-genome doublings 1.
